Somatic mutation profile of tumor specimen TCGA-64-1681-01A (aliquot TCGA-64-1681-01A-11D-2063-08) from TCGA case TCGA-64-1681, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 61.7 years (22,525 days).
Specimen TCGA-64-1681-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d308e3a5-99a2-4cd0-9869-26ff76a6dd75.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-64-1681-10A (Blood Derived Normal), aliquot TCGA-64-1681-10A-01D-2063-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0e6f702b-dd24-4d27-87ff-d2dd264c9093

The open-access MAF lists 69 somatic variants for this specimen: 56 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 12, Nonsense Mutation 7, In Frame Del 2, Frame Shift Ins 1, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 40/124 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs879253911, CM941328, COSV52694461, COSV52816009, COSV53014483, COSV53470757; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA5 | c.2383G>T p.D795Y | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67016139; called by muse, mutect2, varscan2
- ADGRG2 | c.304G>A p.G102S (on ENST00000379869 / NM_001079858.3; = p.G99S on NM_005756.4) | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.611); catalogued as COSV61338143; called by muse, varscan2
- AKAP6 | c.4262A>T p.K1421M | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.41); catalogued as COSV55208566; called by muse, mutect2, varscan2
- AMER1 | c.634C>T p.P212S | Missense Mutation (SNP) | VAF 6/122 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.031); catalogued as COSV57656908; called by muse, mutect2
- AMOT | c.1924C>T p.Q642* (on ENST00000371959 / NM_001113490.1; = p.Q233* on NM_133265.3) | Nonsense Mutation (SNP) | VAF 48/197 reads (24%) | catalogued as COSV59061728; called by muse, mutect2, varscan2
- ARHGAP6 | c.60C>A p.S20R | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.228); catalogued as COSV100498935, COSV61637003; called by muse, mutect2, varscan2
- ARID1A | c.5680C>T p.Q1894* | Nonsense Mutation (SNP) | VAF 65/136 reads (48%) | catalogued as COSV61374094; called by muse, mutect2, varscan2
- ATM | c.2692T>G p.L898V | Missense Mutation (SNP) | VAF 19/150 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.612); catalogued as COSV53734137; called by muse, mutect2, varscan2
- BCORL1 | c.3761A>G p.E1254G | Missense Mutation (SNP) | VAF 20/276 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54392436; called by muse, mutect2
- BTK | c.1426T>A p.Y476N | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as CM950166, CX094305, COSV58118225; called by muse, mutect2, varscan2
- CCDC178 | c.473A>G p.E158G | Missense Mutation (SNP) | VAF 4/67 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as COSV55765583; called by muse, mutect2
- CCDC87 | c.1513G>A p.D505N | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as COSV59578655; called by muse, mutect2
- CD1E | c.265G>T p.E89* | Nonsense Mutation (SNP) | VAF 5/41 reads (12%) | catalogued as COSV63770452, COSV63772935; called by muse, mutect2, varscan2
- CLDN22 | c.102G>C p.K34N | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60109175; called by muse, mutect2
- CLEC16A | c.2954C>G p.P985R | Missense Mutation (SNP) | VAF 8/141 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs1490399396, COSV55489154; called by muse, mutect2
- DCAF4L1 | c.704C>T p.T235M | Missense Mutation (SNP) | VAF 28/191 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV60786836; called by muse, mutect2, varscan2
- F8 | c.5568T>G p.Y1856* | Nonsense Mutation (SNP) | VAF 14/158 reads (9%) | catalogued as CM980704, COSV64271027; called by muse, mutect2
- FANCD2 | c.1799C>G p.A600G | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.009); catalogued as COSV55035163; called by muse, mutect2, varscan2
- FPR1 | c.379G>A p.V127I | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.954); catalogued as rs186613919; called by muse, mutect2, varscan2
- GPR34 | c.356A>G p.K119R | Missense Mutation (SNP) | VAF 22/428 reads (5%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV59363796; called by muse, mutect2
- HOOK3 | c.1148C>G p.S383C | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV56880288, COSV56882823; called by mutect2, varscan2
- HPS3 | c.479G>C p.S160T | Missense Mutation (SNP) | VAF 46/95 reads (48%) | SIFT tolerated (0.95); PolyPhen benign (0.009); catalogued as rs979740599, COSV56053354, COSV56055515; called by muse, mutect2, varscan2
- KATNIP | c.310G>T p.D104Y | Missense Mutation (SNP) | VAF 13/132 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.947); catalogued as COSV55176148; called by muse, mutect2, varscan2
- KRT14 | c.100G>A p.V34I | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs762702328, COSV51420680; called by muse, mutect2, varscan2
- NCAPG2 | c.2668G>C p.D890H | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV104369778, COSV51985905; called by muse, mutect2, varscan2
- NEFH | c.994C>G p.L332V | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV60216029; called by muse, mutect2, varscan2
- NOG | c.584C>T p.S195F | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV60446832; called by muse, mutect2
- NWD1 | c.2837T>G p.F946C | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as COSV60339497; called by muse, mutect2
- OR14A16 | c.47C>G p.S16C | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV62926293; called by muse, mutect2
- OR2T10 | c.502T>G p.F168V | Missense Mutation (SNP) | VAF 12/161 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV57896411; called by muse, mutect2
- OR4C11 | c.310T>A p.L104I | Missense Mutation (SNP) | VAF 36/392 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV56352625; called by muse, mutect2
- PCDH10 | c.2913C>A p.S971R | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV52090078; called by muse, mutect2, varscan2
- PCDH15 | c.1827T>A p.N609K | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.667); catalogued as COSV57278476; called by muse, mutect2, varscan2
- PTCHD1 | c.1955A>C p.K652T | Missense Mutation (SNP) | VAF 7/147 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as COSV65059464, COSV65062067; called by muse, mutect2
- PTPRT | c.2915G>A p.W972* | Nonsense Mutation (SNP) | VAF 6/117 reads (5%) | catalogued as COSV61969190; called by muse, mutect2
- RBBP6 | c.2572G>A p.E858K | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.453); catalogued as COSV60504000; called by muse, mutect2
- RORB | c.862G>C p.A288P (on ENST00000396204 / NM_001365023.1; = p.A277P on NM_006914.4) | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65334122; called by muse, mutect2, varscan2
- TBATA | c.310G>T p.D104Y | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54717791; called by muse, mutect2, varscan2
- TGFBR1 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057524497, COSV66625207, COSV66626776; ClinVar: uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- TMEM200A | c.649C>T p.R217W | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.153); catalogued as rs267600805, COSV51648937, COSV99758850; called by muse, mutect2, varscan2
- TSTD2 | c.365C>G p.S122* | Nonsense Mutation (SNP) | VAF 7/113 reads (6%) | catalogued as COSV57845242; called by muse, mutect2
- TTC3 | c.3078G>T p.K1026N | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61288031; called by muse, mutect2, varscan2
- UBR5 | c.6682G>A p.E2228K | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.163); catalogued as COSV55282961; called by muse, mutect2, varscan2
- UNC79 | c.5206T>C p.S1736P (on ENST00000393151 / NM_001346218.2; = p.S1559P on NM_020818.5) | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV56375306; called by muse, mutect2, varscan2
- ZNF382 | c.756G>T p.K252N | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as COSV99498038; called by muse, mutect2
- ZNF423 | c.3099C>A p.C1033* (on ENST00000563137 / NM_001379286.1; = p.C1025* on NM_015069.4) | Nonsense Mutation (SNP) | VAF 12/40 reads (30%) | catalogued as rs772683449, COSV52181987; called by muse, mutect2, varscan2
- ZNF547 | c.56A>G p.Y19C | Missense Mutation (SNP) | VAF 14/251 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.917); catalogued as COSV56579956; called by muse, mutect2
- ZNF664 | c.572G>C p.R191T | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61877435; called by muse, mutect2, varscan2
- AGMAT | c.524dup p.H176Afs*36 | Frame Shift Ins (INS) | VAF 13/114 reads (11%) | called by mutect2, pindel, varscan2
- CD9 | c.373del p.Y125Tfs*8 | Frame Shift Del (DEL) | VAF 24/94 reads (26%) | called by mutect2, pindel, varscan2
- IRF2BP2 | c.1613_1615del p.I538del | In Frame Del (DEL) | VAF 45/108 reads (42%) | called by mutect2, pindel, varscan2
- KDM4A | c.965_967del p.R322del | In Frame Del (DEL) | VAF 21/96 reads (22%) | called by mutect2, pindel, varscan2
- LMO7 | c.3824C>A p.T1275N (on ENST00000357063; = p.T956N on NM_005358.5) | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.662); called by muse, mutect2
- TRAV10 | c.295A>C p.T99P | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- ADGRA3 | c.2514C>T p.A838= | Silent (SNP) | VAF 5/92 reads (5%) | catalogued as COSV51561284, COSV51567203; called by muse, mutect2
- ADGRG6 | c.2472A>T p.A824= | Silent (SNP) | VAF 21/165 reads (13%) | catalogued as COSV51588788; called by muse, mutect2, varscan2
- AGXT | c.798C>G p.V266= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as CD154472, CX983844, COSV56753413, COSV56754189; called by muse, mutect2, varscan2
- EYA1 | c.75C>T p.L25= | Silent (SNP) | VAF 28/171 reads (16%) | catalogued as rs185389264, COSV58159317; called by muse, mutect2, varscan2
- F13A1 | c.2148A>G p.R716= | Silent (SNP) | VAF 14/90 reads (16%) | catalogued as COSV53555828; called by muse, mutect2, varscan2
- GRIN2D | c.1809C>T p.I603= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as COSV54377691; called by muse, mutect2, varscan2
- IL32 | c.612C>G p.L204= (on ENST00000396890 / NM_001308078.4; = p.L158= on NM_004221.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 68/193 reads (35%) | catalogued as COSV50403999; called by muse, mutect2, varscan2
- MYH8 | c.1125A>G p.Q375= | Silent (SNP) | VAF 30/193 reads (16%) | catalogued as COSV67961793; called by muse, mutect2, varscan2
- OR8I2 | c.702G>A p.Q234= | Silent (SNP) | VAF 15/123 reads (12%) | catalogued as rs1347566872, COSV56167029; called by muse, mutect2, varscan2
- RB1CC1 | c.510G>A p.K170= | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as COSV50244541; called by muse, mutect2, varscan2
- SHROOM4 | c.2868T>G p.T956= | Silent (SNP) | VAF 24/52 reads (46%) | catalogued as COSV56786559, COSV99172967; called by muse, mutect2, varscan2
- TBC1D9B | c.3027A>G p.K1009= (on ENST00000356834 / NM_198868.3; = p.K992= on NM_015043.4) | Silent (SNP) | VAF 14/123 reads (11%) | catalogued as COSV62281462; called by muse, mutect2, varscan2
- TTN | c.10361-5055G>A | Intron (SNP) | VAF 10/141 reads (7%) | catalogued as rs559696231, COSV59944068; called by muse, mutect2
